CCDI case PBBVFA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6c752de2-53e8-4841-8e0b-03f6d44394a2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 9.7 years (3,555 days).

Biospecimens (3 samples)
- Sample 0DI1JV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI1V4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI202: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
